Surgical pathology report (de-identified scan), TCGA case TCGA-D7-8570, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Greater Poland Cancer Center, specimen TCGA-D7-8570-01A (Primary Tumor).

Material:

1) Material: stomach, Method of collection: Total organ resection

Histopathological diagnosis:

Examination performed

Adenocarcinoma tubulare partim male differentiatum ventriculi. Tubular adenocarcinoma of the stomach, poorly differentiated. Metastases carcinomatosae in lymphonodis NO XIII/XXIV. G3, pT3, pN3a. Cancer metastases in the lymph nodes NO XIII/XXIV. Typus intestinalis sec. Lauren. Intestinal type Lauren

Macroscopic description:

Specimen consisting of the stomach, having been incised along the greater curvature, sized 18 x 15 cm with a 1.5 cm segment of the oesophagus and the omentum sized 50 x 32 cm. Tumour sized 4 x 2.5 x 1.2 cm in the orifice region, covering 50% of the orifice circumference. Distance from the proximal end: 2.3 cm, from distal end: 12.5 cm.

Microscopic description:

Adenocarcinoma tubulare partim male differentiatum G3. Cancer infiltrates the muscular membrane and reaches the serosa. The omentum and surgical incision lines free of neoplastic lesions. LYMPH NODES:

- periorificial: metastases carcinomatosae in lymphonodis (NO VIII/XIII)
- lesser curvature: metastases carcinomatosae in lymphonodis (No V/V).
- pyloric: lymphonodulitis reactiva (No IV).

**HER2 protein stained with Ventana's Pathway HER-2/neu (4B5) Rabbit Monoclonal Antibody.
Negative reaction in invasive cancerous cells (Score = 0)**

Assistant:

CONTACT YOUR DOCTOR WITH THIS REPORT!

Source: NCI Genomic Data Commons file e43c4ea3-7980-4746-8f06-eecff96f7320 (TCGA-D7-8570.44E6D9B3-E86F-431A-8D80-6F992542C47D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).